Somatic mutation profile of tumor specimen C3N-02573-01 (aliquot CPT0183450008) from CPTAC case C3N-02573, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 41.9 years (15,316 days).
Specimen C3N-02573-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ab9e2bb-d233-4fa9-a6fd-38532f82b85a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02573-71 (Blood Derived Normal), aliquot CPT0183510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59854ca-7505-4f71-bc04-ee7b06e9d8fb

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Intron 4, 5'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 56/458 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 54/415 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519962, CM147649, COSV61689171, COSV61689611, COSV61697840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 48/410 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 104/929 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1327464717; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4516C>T p.R1506W | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781474522; called by muse, mutect2, varscan2
- AMPH | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348357360, COSV57737817; called by muse, mutect2, varscan2
- BRCA2 | c.8524C>T p.R2842C | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359104, COSV66450665, COSV66453321; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CACNG4 | c.304+1G>A p.X102_splice | Splice Site (SNP) | VAF 26/272 reads (10%) | catalogued as rs774987460, COSV100047924; called by muse, mutect2
- CES2 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756554216; called by muse, mutect2, varscan2
- CLPX | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV55644577; called by muse, mutect2, varscan2
- ENGASE | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 73/605 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs369232286, COSV100285726; called by muse, mutect2, varscan2
- FOXI1 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 103/850 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1386572006; called by muse, mutect2, varscan2
- FREM3 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs532088660; called by muse, mutect2, varscan2
- GRIA1 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 84/724 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs139089198, COSV53588447; called by muse, mutect2, varscan2
- HERC1 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs761166996, COSV71246981; called by muse, mutect2
- KIF26B | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 47/445 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1034978766, COSV68572526; called by muse, mutect2, varscan2
- KMT2D | c.4435C>T p.Q1479* | Nonsense Mutation (SNP) | VAF 39/279 reads (14%) | catalogued as COSV56434785; called by muse, mutect2, varscan2
- LAMC3 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs900991986; called by muse, mutect2
- LHCGR | c.2079G>C p.K693N | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as rs759440300; called by muse, mutect2
- LINC02210-CRHR1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1258391158, COSV99524313; called by muse, mutect2, varscan2
- MAP3K6 | c.3289del p.R1097Vfs*23 | Frame Shift Del (DEL) | VAF 54/494 reads (11%) | catalogued as rs1418996847; called by mutect2, pindel, varscan2
- MEPCE | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 66/642 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1430244677, COSV52769750; called by muse, mutect2
- NID1 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 66/595 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs1429973418, COSV51614984; called by muse, mutect2, varscan2
- PXDNL | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs537952252, COSV62487421; called by muse, mutect2, varscan2
- ZNF780A | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777421693; called by muse, mutect2, varscan2
- ACO2 | c.1735C>G p.L579V | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKR1C4 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 39/322 reads (12%) | called by muse, mutect2, varscan2
- CASK | c.125T>G p.I42S | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- CTAGE1 | c.1613A>C p.Q538P | Missense Mutation (SNP) | VAF 119/557 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DENND5A | c.469C>A p.H157N | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF2S3 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM47C | c.2798A>T p.H933L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.096); called by muse, mutect2
- FBN3 | c.7440C>A p.H2480Q | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- FBXO33 | c.239_241del p.F80del | In Frame Del (DEL) | VAF 44/240 reads (18%) | called by pindel, varscan2
- HUWE1 | c.8745G>T p.E2915D | Missense Mutation (SNP) | VAF 61/581 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.2459C>G p.A820G | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- KCNQ4 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 60/576 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB2 | c.1722C>G p.C574W | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SHISA9 | c.1108G>C p.G370R | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2
- TERT | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 30/978 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- ABHD14A-ACY1 | c.1336C>T p.L446= | Silent (SNP) | VAF 44/428 reads (10%) | called by muse, mutect2
- ADD2 | c.1950C>T p.N650= | Silent (SNP) | VAF 58/465 reads (12%) | catalogued as rs1553365524, COSV52458845; called by muse, mutect2, varscan2
- ASPSCR1 | c.297C>T p.D99= | Silent (SNP) | VAF 43/375 reads (11%) | catalogued as rs748292573; called by muse, mutect2, varscan2
- ATP8B3 | c.1680C>T p.A560= | Silent (SNP) | VAF 67/608 reads (11%) | catalogued as rs764850311; called by muse, mutect2, varscan2
- NCAPD2 | c.870G>C p.L290= | Silent (SNP) | VAF 25/255 reads (10%) | catalogued as COSV59701572; called by muse, mutect2, varscan2
- PDZK1 | c.270T>C p.D90= | Silent (SNP) | VAF 31/370 reads (8%) | called by muse, varscan2
- PSD | c.282C>T p.P94= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs767634674; called by muse, mutect2, varscan2
- PTPRQ | c.276A>G p.T92= (on ENST00000616559; = p.T50= on NM_001145026.2) | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- PTPRT | c.2412C>T p.A804= | Silent (SNP) | VAF 30/391 reads (8%) | catalogued as rs368232579; called by muse, mutect2
- SORCS1 | c.609A>G p.T203= | Silent (SNP) | VAF 19/238 reads (8%) | called by muse, mutect2
- AL132655.6 | chr20:58840572 G>A | 5'Flank (SNP) | VAF 35/273 reads (13%) | catalogued as rs776413759, COSV58342706; called by muse, mutect2, varscan2
- EFHB | chr3:19936288 G>A | 5'Flank (SNP) | VAF 11/73 reads (15%) | catalogued as rs994695408; called by muse, mutect2
- MIR485 | n.54C>T | RNA (SNP) | VAF 28/140 reads (20%) | catalogued as rs751189950; called by muse, mutect2, varscan2
- NEDD9 | c.460-7330T>C | Intron (SNP) | VAF 39/380 reads (10%) | called by muse, mutect2
- RNF121 | c.244-4566C>G | Intron (SNP) | VAF 38/397 reads (10%) | called by muse, mutect2
- RPL7L1P9 | chr2:217756067 C>G | 3'Flank (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- SLC25A3 | c.645-209G>C | Intron (SNP) | VAF 20/423 reads (5%) | called by muse, mutect2
- TSN | c.67-660C>G | Intron (SNP) | VAF 20/189 reads (11%) | catalogued as rs1202689476, COSV67606000; called by muse, mutect2
